Somatic mutation profile of tumor specimen BA2905D (aliquot aq-BA2905D) from BEATAML1.0 case 2019, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.3 years (28,218 days).
Specimen BA2905D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5f3ca25-329b-43ba-8dc5-b2b11eadf02d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2398D (Solid Tissue Normal), aliquot aq-BA2398D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b598a2e5-3ae5-4b2a-bafb-2550ce6433f3

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Nonsense Mutation 1, Intron 1, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAB33B | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs762852071; called by muse, mutect2, varscan2
- COQ8B | c.1572G>T p.Q524H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- CYP2W1 | c.156G>C p.Q52H | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- GPR45 | c.258C>A p.C86* | Nonsense Mutation (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- JAK3 | c.1946C>A p.S649Y | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- POLR2B | c.2321C>A p.A774E | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF185 | c.1259C>A p.A420D | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- KIF13B | c.3723G>C p.T1241= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV72954444; called by muse, mutect2, varscan2
- AL662899.2 | c.367+301C>A | Intron (SNP) | VAF 27/82 reads (33%) | catalogued as COSV65507674; called by muse, mutect2, varscan2
- GPATCH8 | c.*1807A>C | 3'UTR (SNP) | VAF 52/366 reads (14%) | called by muse, mutect2, varscan2
